Somatic mutation profile of tumor specimen ALCH-B3J7-TTP1-A (aliquot ALCH-B3J7-TTP1-A-2-0-D-A80D-36) from ALCHEMIST case ALCH-B3J7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.1 years (22,686 days).
Specimen ALCH-B3J7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b1baed0d-ad1e-4171-954d-ea33bbff1b1b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3J7-NB1-A (Blood Derived Normal), aliquot ALCH-B3J7-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2298eae8-9025-4fe5-a2f4-9f9726255f71

The open-access MAF lists 107 somatic variants for this specimen: 77 protein-altering or splice-affecting, 21 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 64, Silent 21, Nonsense Mutation 7, Intron 6, Frame Shift Ins 2, RNA 2, Frame Shift Del 2, 5'UTR 1, In Frame Ins 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ASB2 | c.1107C>A p.F369L | Missense Mutation (SNP) | VAF 9/64 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs754637892, COSV60114614; called by muse, mutect2, varscan2
- DCDC1 | c.111G>T p.L37F | Missense Mutation (SNP) | VAF 4/72 reads (6%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0.006); catalogued as COSV60845883; called by muse, mutect2
- EP300 | c.3766C>T p.Q1256* | Nonsense Mutation (SNP) | VAF 16/388 reads (4%) | catalogued as COSV54335815; called by muse, mutect2
- EP300 | c.5392G>T p.E1798* | Nonsense Mutation (SNP) | VAF 9/162 reads (6%) | catalogued as COSV54342770; called by muse, mutect2
- ERBB2 | c.2326_2327insTAT p.G776delinsVC | In Frame Ins (INS) | VAF 9/49 reads (18%) | catalogued as COSV54064203, COSV54064477, COSV54066307, COSV54066802, COSV54077015, COSV99507093; called by mutect2, pindel
- ERCC6 | c.1623G>C p.Q541H | Missense Mutation (SNP) | VAF 22/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs766162602; called by muse, mutect2
- FBN2 | c.7015G>A p.E2339K | Missense Mutation (SNP) | VAF 9/230 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.396); catalogued as COSV99326648; called by muse, mutect2
- GRIN2B | c.2791G>A p.V931I | Missense Mutation (SNP) | VAF 35/170 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.037); catalogued as rs199941557, COSV74206507; called by muse, mutect2, varscan2
- HLTF | c.2776C>G p.R926G | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs768794352, COSV59499943, COSV99047597; called by muse, varscan2
- KALRN | c.7512G>A p.W2504* (on ENST00000360013 / NM_001024660.4; = p.W807* on NM_007064.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 7/175 reads (4%) | catalogued as COSV52250620; called by muse, mutect2
- KHDRBS1 | c.44C>T p.S15L | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT tolerated, low confidence (0.26); PolyPhen possibly damaging (0.602); catalogued as rs760747849; called by muse, mutect2
- KIF5A | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 8/126 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761812789, COSV54051340; called by muse, mutect2
- M1AP | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 8/207 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as rs1558641099; called by muse, mutect2
- PDCD7 | c.748C>A p.R250S | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.7); catalogued as COSV99200141; called by muse, mutect2
- PDS5A | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.908); catalogued as rs1420372778; called by muse, mutect2
- PLEKHH1 | c.1588G>A p.V530I | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.022); catalogued as rs770331514, COSV61281513, COSV61282648; called by mutect2, varscan2
- PRADC1 | c.358G>C p.D120H | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV57819977; called by muse, mutect2
- RGMB | c.354G>C p.Q118H (on ENST00000513185 / NM_001366508.1; = p.Q159H on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/184 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100374992; called by muse, mutect2
- SAGE1 | c.1476G>C p.K492N | Missense Mutation (SNP) | VAF 8/152 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100188123; called by muse, mutect2
- SUPT16H | c.2227G>A p.E743K | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as COSV104369733, COSV53527152; called by muse, mutect2
- TH | c.1211C>T p.T404M (on ENST00000381178 / NM_199292.3; = p.T373M on NM_000360.4) | Missense Mutation (SNP) | VAF 13/109 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868563700; called by muse, mutect2, varscan2
- TRIM29 | c.578C>T p.S193F | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1345968919; called by muse, mutect2
- TTC37 | c.3376C>T p.Q1126* | Nonsense Mutation (SNP) | VAF 16/402 reads (4%) | catalogued as COSV62454506, COSV99072469; called by muse, mutect2
- ZMYM2 | c.1835G>C p.C612S | Missense Mutation (SNP) | VAF 29/193 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67033927; called by muse, mutect2, varscan2
- ZP1 | c.104C>T p.P35L | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.45); PolyPhen benign (0.003); catalogued as COSV99612943; called by muse, mutect2
- ACSM5 | c.512C>T p.S171F | Missense Mutation (SNP) | VAF 8/247 reads (3%) | SIFT tolerated (0.11); PolyPhen benign (0.436); called by muse, mutect2
- AKAP9 | c.11131C>T p.Q3711* (on ENST00000359028; = p.Q3687* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/122 reads (13%) | called by muse, mutect2
- AMIGO2 | c.662G>A p.R221K | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- ARID1A | c.5870dup p.D1957Efs*6 | Frame Shift Ins (INS) | VAF 10/72 reads (14%) | called by mutect2, pindel, varscan2
- C10orf71 | c.2248G>A p.E750K | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CD163 | c.3350C>T p.S1117F | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2
- CENPE | c.6804G>A p.M2268I | Missense Mutation (SNP) | VAF 10/142 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0); called by muse, mutect2
- CHD1L | c.1505G>C p.G502A | Missense Mutation (SNP) | VAF 5/94 reads (5%) | SIFT tolerated (0.34); PolyPhen benign (0.167); called by muse, mutect2
- CREB3L2 | c.906C>G p.I302M | Missense Mutation (SNP) | VAF 8/260 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CTNNA1 | c.1922C>T p.S641F | Missense Mutation (SNP) | VAF 7/167 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2
- DIAPH2 | c.2386A>G p.S796G | Missense Mutation (SNP) | VAF 5/104 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- DPY19L3 | c.1839G>C p.Q613H | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- EIF3F | c.1069A>T p.R357* | Nonsense Mutation (SNP) | VAF 9/58 reads (16%) | called by muse, mutect2, varscan2
- FAM135B | c.2374G>A p.D792N | Missense Mutation (SNP) | VAF 9/119 reads (8%) | SIFT tolerated (0.41); PolyPhen benign (0.023); called by muse, mutect2
- GATAD2A | c.1293G>C p.E431D | Missense Mutation (SNP) | VAF 4/104 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.229); called by muse, mutect2
- GRK5 | c.1129G>A p.E377K | Missense Mutation (SNP) | VAF 5/69 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- GRM7 | c.1445A>G p.Y482C | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- HGH1 | c.590A>G p.D197G | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- IRS4 | c.350A>T p.K117M | Missense Mutation (SNP) | VAF 9/114 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- ITGB4 | c.5329+1G>A p.X1777_splice | Splice Site (SNP) | VAF 7/140 reads (5%) | called by muse, mutect2
- ITSN1 | c.2429C>T p.P810L | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); called by muse, mutect2
- LCA5 | c.1546G>C p.E516Q | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.182); called by muse, mutect2
- LRATD2 | c.740T>G p.L247R | Missense Mutation (SNP) | VAF 16/83 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- LRP6 | c.2274del p.E759Kfs*15 | Frame Shift Del (DEL) | VAF 10/100 reads (10%) | called by mutect2, pindel
- MAGOH | c.73G>C p.E25Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- MINPP1 | c.926A>T p.D309V | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- NTRK3 | c.418A>G p.T140A | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.403); called by muse, mutect2
- NVL | c.2525dup p.D843Gfs*6 | Frame Shift Ins (INS) | VAF 20/118 reads (17%) | called by mutect2, pindel, varscan2
- PCDH11X | c.2395G>A p.E799K | Missense Mutation (SNP) | VAF 21/428 reads (5%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.542); called by muse, mutect2
- PM20D2 | c.198C>G p.F66L | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (0.56); PolyPhen benign (0.009); called by muse, mutect2
- PPRC1 | c.1847C>T p.S616L | Missense Mutation (SNP) | VAF 7/91 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0); called by muse, mutect2
- PRPF3 | c.521C>T p.S174F | Missense Mutation (SNP) | VAF 12/206 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.086); called by muse, mutect2
- RAG1 | c.328C>G p.L110V | Missense Mutation (SNP) | VAF 12/300 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.067); called by muse, mutect2
- RGS3 | c.2050G>A p.E684K (on ENST00000350696 / NM_001282923.2; = p.E403K on NM_130795.4) | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.009); called by muse, mutect2
- ROS1 | c.497del p.F166Sfs*34 | Frame Shift Del (DEL) | VAF 8/79 reads (10%) | called by mutect2, pindel, varscan2
- SMARCA1 | c.1661G>T p.R554M | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2
- SMCO2 | c.153C>G p.I51M | Missense Mutation (SNP) | VAF 9/162 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.481); called by muse, mutect2
- SMIM4 | c.75C>G p.F25L | Missense Mutation (SNP) | VAF 12/236 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.104); called by muse, mutect2
- SPPL2A | c.1400A>G p.Y467C | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SREK1 | c.1314G>C p.M438I | Missense Mutation (SNP) | VAF 20/260 reads (8%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- STIM1 | c.247G>A p.V83M | Missense Mutation (SNP) | VAF 11/344 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TIGD5 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.754); called by muse, mutect2
- TJP1 | c.4540G>A p.E1514K | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.05); called by muse, mutect2
- TNKS | c.1846G>A p.D616N | Missense Mutation (SNP) | VAF 9/239 reads (4%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.656); called by muse, mutect2
- TP53BP1 | c.5410C>G p.L1804V | Missense Mutation (SNP) | VAF 4/75 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- TUBB4A | c.795C>G p.F265L | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.098); called by muse, mutect2
- TUBD1 | c.676G>A p.D226N | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.169); called by muse, mutect2
- UNC80 | c.4732A>T p.K1578* | Nonsense Mutation (SNP) | VAF 19/115 reads (17%) | called by muse, mutect2, varscan2
- VPS29 | c.401C>G p.S134C | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZBTB40 | c.3682G>C p.D1228H | Missense Mutation (SNP) | VAF 10/127 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- ZFC3H1 | c.1585G>C p.E529Q | Missense Mutation (SNP) | VAF 6/113 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2
- ZNF90 | c.930G>C p.E310D | Missense Mutation (SNP) | VAF 10/297 reads (3%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); called by muse, mutect2
- ABCC11 | c.1995C>T p.D665= | Silent (SNP) | VAF 16/98 reads (16%) | catalogued as rs150571618; called by muse, mutect2, varscan2
- ACTL7B | c.450C>T p.S150= | Silent (SNP) | VAF 14/55 reads (25%) | catalogued as COSV65927683; called by muse, mutect2, varscan2
- AFTPH | c.1593G>A p.G531= | Silent (SNP) | VAF 11/259 reads (4%) | called by muse, mutect2
- ALLC | c.1041C>T p.H347= | Silent (SNP) | VAF 20/114 reads (18%) | catalogued as rs763067976, COSV52992955; called by muse, mutect2, varscan2
- AREL1 | c.2307C>T p.L769= | Silent (SNP) | VAF 9/124 reads (7%) | called by muse, mutect2
- ATOH8 | c.381G>A p.P127= | Silent (SNP) | VAF 3/17 reads (18%) | catalogued as rs887150499; called by muse, varscan2
- B4GALT7 | c.507C>G p.L169= | Silent (SNP) | VAF 8/118 reads (7%) | called by muse, mutect2
- BPNT2 | c.801T>A p.G267= | Silent (SNP) | VAF 77/320 reads (24%) | called by muse, mutect2, varscan2
- DHX58 | c.240G>T p.L80= | Silent (SNP) | VAF 13/171 reads (8%) | catalogued as COSV99288459; called by muse, mutect2
- DNAH1 | c.999G>T p.G333= | Silent (SNP) | VAF 5/44 reads (11%) | catalogued as rs754698653, COSV70233558; called by mutect2, varscan2
- NEK4 | c.498C>T p.L166= | Silent (SNP) | VAF 13/208 reads (6%) | called by muse, mutect2
- PIK3CD | c.1083G>A p.S361= | Silent (SNP) | VAF 6/156 reads (4%) | catalogued as rs1001849803, COSV63129675; called by muse, mutect2
- PLCH2 | c.1368C>G p.L456= | Silent (SNP) | VAF 7/52 reads (13%) | catalogued as COSV99616686; called by muse, mutect2, varscan2
- PSMD2 | c.420C>G p.L140= | Silent (SNP) | VAF 9/165 reads (5%) | called by muse, mutect2
- SCN4A | c.5166C>G p.L1722= | Silent (SNP) | VAF 9/74 reads (12%) | catalogued as COSV101438630; called by muse, mutect2, varscan2
- SEC31B | c.453G>A p.L151= | Silent (SNP) | VAF 13/164 reads (8%) | catalogued as rs765309604; called by muse, mutect2
- SHH | c.166C>T p.L56= | Silent (SNP) | VAF 18/176 reads (10%) | catalogued as CD095906, COSV99793262; called by muse, mutect2
- SLC7A13 | c.222C>T p.F74= | Silent (SNP) | VAF 7/156 reads (4%) | catalogued as COSV99878843; called by muse, mutect2
- TNNT3 | c.351G>A p.Q117= (on ENST00000397301 / NM_001367846.1; = p.Q106= on NM_006757.4) | Silent (SNP) | VAF 20/156 reads (13%) | called by muse, mutect2, varscan2
- ZNF529 | c.468A>G p.E156= | Silent (SNP) | VAF 8/169 reads (5%) | catalogued as rs1211272228; called by muse, mutect2
- ZNF827 | c.1851C>T p.F617= | Silent (SNP) | VAF 29/242 reads (12%) | catalogued as COSV65226315; called by muse, mutect2, varscan2
- AC012485.1 | n.369G>A | RNA (SNP) | VAF 9/226 reads (4%) | catalogued as rs1401060427; called by muse, mutect2
- CHRNB1 | c.462+35C>G | Intron (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- MLH1 | c.1732-16T>A | Intron (SNP) | VAF 10/195 reads (5%) | called by muse, mutect2
- PCNX1 | c.4577+1334C>T | Intron (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- SHISA9 | c.563+5911C>T | Intron (SNP) | VAF 16/108 reads (15%) | called by muse, mutect2, varscan2
- SPATA31C1 | n.1650C>T | RNA (SNP) | VAF 11/227 reads (5%) | called by muse, mutect2
- ST20-MTHFS | c.-72C>T | 5'UTR (SNP) | VAF 3/39 reads (8%) | called by muse, mutect2
- TEDC1 | c.892-27C>T | Intron (SNP) | VAF 13/85 reads (15%) | catalogued as rs782760633; called by muse, mutect2, varscan2
- TMTC1 | c.939-26607G>A | Intron (SNP) | VAF 14/254 reads (6%) | called by muse, mutect2
